MMRF case MMRF_2543 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/706d1666-1cd7-4636-b827-229a1293656f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.8 years (25,125 days); ISS stage: II; Days to last known disease status: 549 days (1.5 years); Days to last follow up: 549 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -83: M Protein 5.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2320 mg/dL; Immunoglobulin G 73.1 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 4.3 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.04 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 87.5 µmol/L; Albumin 26 g/L; Total Protein 11.6 g/dL; Glucose 4.29 mmol/L; C-Reactive Protein 0.27 mg/dL.
- Day 11 (ECOG 1): Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 1.65 mmol/L; Albumin 21 g/L; Total Protein 8.5 g/dL; Glucose 5.5 mmol/L.
- Day 85 (ECOG 1): Hemoglobin 7.13 mmol/L; Leukocytes 5.16 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 58.3 µmol/L; Calcium 2.15 mmol/L; Albumin 26 g/L; Total Protein 5.8 g/dL; Glucose 5.17 mmol/L.
- Day 178 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 3.27 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 7.99 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Glucose 5.23 mmol/L.
- Day 269 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 5.4 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.73 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 8.85 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.18 mmol/L; Albumin 28 g/L; Total Protein 5.8 g/dL; Glucose 5.56 mmol/L.
- Day 375 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 6.96 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.69 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 5.35 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 5.9 g/dL; Glucose 5.34 mmol/L.
- Day 443 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 6.64 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.68 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 10 mmol/L; Leukocytes 7.11 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 5.8 g/dL; Glucose 4.84 mmol/L.
- Day 549 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 8.44 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.77 g/L; Beta 2 Microglobulin 2.2 µg/mL; Hemoglobin 10.3 mmol/L; Leukocytes 6.58 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 324 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -83: Weight: 72 kg; Height: 184 cm.

Biospecimens (2 samples)
- Sample MMRF_2543_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -83 days.
- Sample MMRF_2543_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -83 days.
